Somatic mutation profile of cancer-model specimen HCM-WCMC-1340-C54-85A (3D Organoid; aliquot HCM-WCMC-1340-C54-85A-01D-A937-36), derived from the primary tumor of HCMI case HCM-WCMC-1340-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; AJCC pathologic stage: Stage I; FIGO stage: Stage IIIA; Age at diagnosis: 64.0 years (23,370 days).
Specimen HCM-WCMC-1340-C54-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70cfceb3-55ad-4930-95a7-c0d76b79197d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-1340-C54-12A (Saliva), aliquot HCM-WCMC-1340-C54-12A-01D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2721010c-bb2f-40d1-b3c5-962aeed701e0

The open-access MAF lists 75 somatic variants for this specimen: 53 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 20, Frame Shift Del 3, Nonsense Mutation 2, Nonstop Mutation 1, 5'Flank 1, Splice Region 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 138/290 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.733G>A p.G245S | Missense Mutation (SNP) | VAF 169/381 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.454_466del p.P152Afs*14 | Frame Shift Del (DEL) | VAF 153/419 reads (37%) | catalogued as rs876659215; ClinVar: pathogenic; called by pindel, varscan2
- ADAM7 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 31/516 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99443322; called by muse, mutect2
- ADGRB3 | c.1949G>A p.S650N | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754582738; called by muse, mutect2, varscan2
- ADGRF2 | c.1606A>G p.M536V (on ENST00000296862 / NM_001368115.2; = p.M468V on NM_153839.7) | Missense Mutation (SNP) | VAF 173/369 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748476051; called by muse, mutect2, varscan2
- AHRR | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 32/654 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV100327316; called by muse, mutect2
- AXL | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs753706427, COSV56567403; called by muse, mutect2, varscan2
- CEACAM20 | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 158/158 reads (100%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.625); catalogued as rs745625554, COSV57601380; called by muse, mutect2, varscan2
- CLIC6 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 309/603 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.52); catalogued as rs955086173; called by muse, mutect2, varscan2
- FAM81A | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 263/564 reads (47%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs746953331, COSV55676948; called by muse, mutect2, varscan2
- GPR45 | c.967G>A p.V323I | Missense Mutation (SNP) | VAF 209/455 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs1285738675, COSV51523362; called by muse, mutect2, varscan2
- HEATR5B | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 205/460 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158767769, COSV51849694; called by muse, mutect2, varscan2
- MFSD11 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1441671495; called by muse, mutect2, varscan2
- MRGPRX1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 274/274 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as rs1244425426, COSV57107509, COSV57110283; called by muse, mutect2, varscan2
- OBSCN | c.22G>A p.G8R | Missense Mutation (SNP) | VAF 24/785 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1226819387; called by muse, mutect2
- PLXNB2 | c.1102C>T p.H368Y | Missense Mutation (SNP) | VAF 427/427 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as COSV100834261; called by muse, mutect2, varscan2
- POGZ | c.4103C>T p.T1368I | Missense Mutation (SNP) | VAF 211/899 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs138705914; called by muse, mutect2, varscan2
- PPP1R16B | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 187/438 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as rs376987738; called by muse, mutect2, varscan2
- PSG6 | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 183/189 reads (97%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.705); catalogued as COSV51837046; called by muse, mutect2, varscan2
- RELCH | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 98/222 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV99902758; called by muse, mutect2, varscan2
- RNF111 | c.2443G>T p.G815* | Nonsense Mutation (SNP) | VAF 85/197 reads (43%) | catalogued as COSV62084959; called by muse, mutect2, varscan2
- SH3KBP1 | c.295C>G p.R99G | Missense Mutation (SNP) | VAF 128/442 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV65643034; called by muse, mutect2, varscan2
- SPEG | c.2801G>A p.R934H | Missense Mutation (SNP) | VAF 286/564 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as rs1327464996, COSV100405587; called by muse, mutect2, varscan2
- SYNE2 | c.10195C>G p.R3399G | Missense Mutation (SNP) | VAF 151/354 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV59972135; called by muse, mutect2, varscan2
- TAF1 | c.3190T>C p.S1064P (on ENST00000373790 / NM_138923.4; = p.S1085P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 159/320 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52114885; called by muse, mutect2, varscan2
- TJP1 | c.2893A>G p.T965A | Missense Mutation (SNP) | VAF 257/562 reads (46%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as rs766721435; called by muse, mutect2, varscan2
- TSC1 | c.1888_1891del p.K630Qfs*22 | Frame Shift Del (DEL) | VAF 342/376 reads (91%) | catalogued as rs118203595; called by pindel, varscan2
- TUBA3C | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 274/598 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as rs747244144, COSV67138980, COSV67140232; called by muse, mutect2, varscan2
- UBE4B | c.3254C>T p.S1085F (on ENST00000343090 / NM_001105562.3; = p.S956F on NM_006048.5) | Missense Mutation (SNP) | VAF 170/415 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53529298; called by muse, mutect2, varscan2
- UNC13A | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs764119582, COSV53189928; called by muse, mutect2, varscan2
- ZNF385C | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 275/553 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.071); catalogued as rs1478155742; called by muse, mutect2, varscan2
- ARHGAP9 | c.534A>G p.T178= | Splice Region (SNP) | VAF 116/261 reads (44%) | called by muse, mutect2, varscan2
- BAG6 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 722/1128 reads (64%) | SIFT tolerated (0.96); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CAMK2B | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 14/436 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CERKL | c.340A>T p.S114C | Missense Mutation (SNP) | VAF 165/332 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- FUT2 | c.989G>T p.W330L | Missense Mutation (SNP) | VAF 197/417 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRAMD1A | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 52/998 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2
- NAMPT | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 80/204 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSD1 | c.286T>G p.S96A | Missense Mutation (SNP) | VAF 198/406 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- OXTR | c.1170A>C p.*390Cext*24 | Nonstop Mutation (SNP) | VAF 119/119 reads (100%) | called by muse, mutect2, varscan2
- PARD3 | c.1846G>C p.D616H | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PCDHB2 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 329/794 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- PDGFRB | c.1916C>G p.T639R | Missense Mutation (SNP) | VAF 15/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PPFIA1 | c.3467C>T p.S1156L | Missense Mutation (SNP) | VAF 201/679 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ROS1 | c.405T>A p.Y135* | Nonsense Mutation (SNP) | VAF 163/358 reads (46%) | called by muse, mutect2, varscan2
- SLFN14 | c.1753A>C p.K585Q | Missense Mutation (SNP) | VAF 13/296 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- STXBP5L | c.942G>C p.K314N | Missense Mutation (SNP) | VAF 53/53 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM121 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 384/775 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRPS1 | c.2970A>T p.E990D (on ENST00000220888 / NM_001330599.2; = p.E1003D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP11 | c.281G>A p.R94H (on ENST00000218348; = p.R51H on NM_001371072.1) | Missense Mutation (SNP) | VAF 187/404 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.517); called by muse, varscan2
- XPNPEP2 | c.929A>G p.D310G | Missense Mutation (SNP) | VAF 171/472 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB7B | c.522del p.N176Mfs*44 (on ENST00000292176; = p.N210Mfs*44 on NM_001252406.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 733/1210 reads (61%) | called by mutect2, pindel, varscan2
- AAAS | c.807C>A p.I269= | Silent (SNP) | VAF 167/481 reads (35%) | catalogued as rs749004311; called by muse, mutect2, varscan2
- ABHD15 | c.1074T>C p.A358= | Silent (SNP) | VAF 336/646 reads (52%) | called by muse, mutect2, varscan2
- ANKRD62 | c.738T>A p.A246= | Silent (SNP) | VAF 150/335 reads (45%) | called by muse, mutect2, varscan2
- ATP8B2 | c.999C>T p.H333= (on ENST00000672630; = p.H300= on NM_001005855.2) | Silent (SNP) | VAF 216/903 reads (24%) | catalogued as rs773334580; called by muse, mutect2, varscan2
- AXIN2 | c.1953G>C p.S651= | Silent (SNP) | VAF 141/517 reads (27%) | catalogued as rs372086777; called by muse, mutect2, varscan2
- CFAP46 | c.3090G>A p.V1030= | Silent (SNP) | VAF 181/404 reads (45%) | catalogued as COSV63949684; called by muse, mutect2, varscan2
- NKX1-1 | c.1314C>T p.Y438= | Silent (SNP) | VAF 210/406 reads (52%) | called by muse, mutect2, varscan2
- OR1D2 | c.255C>T p.L85= | Silent (SNP) | VAF 278/519 reads (54%) | called by muse, mutect2, varscan2
- OR8K1 | c.879G>A p.P293= | Silent (SNP) | VAF 368/567 reads (65%) | catalogued as rs545105332, COSV54403279; called by muse, mutect2, varscan2
- PRMT1 | c.753C>T p.L251= | Silent (SNP) | VAF 827/1135 reads (73%) | catalogued as rs753591648; called by muse, mutect2, varscan2
- PRR33 | c.639C>A p.T213= | Silent (SNP) | VAF 231/231 reads (100%) | catalogued as rs1263738692; called by muse, mutect2, varscan2
- RNF213 | c.4890G>A p.G1630= | Silent (SNP) | VAF 208/413 reads (50%) | called by muse, mutect2, varscan2
- SLC5A11 | c.810G>A p.P270= | Silent (SNP) | VAF 194/397 reads (49%) | catalogued as rs369610204; called by muse, mutect2, varscan2
- SMAP2 | c.162C>A p.I54= | Silent (SNP) | VAF 195/350 reads (56%) | called by muse, mutect2, varscan2
- STK11IP | c.525G>T p.L175= | Silent (SNP) | VAF 159/364 reads (44%) | called by muse, mutect2, varscan2
- TAP2 | c.1131G>A p.L377= | Silent (SNP) | VAF 196/540 reads (36%) | called by muse, mutect2, varscan2
- TNS1 | c.4476C>T p.S1492= | Silent (SNP) | VAF 154/339 reads (45%) | catalogued as COSV50690287; called by muse, mutect2, varscan2
- TRPC3 | c.696G>A p.P232= (on ENST00000379645 / NM_001366479.2; = p.P159= on NM_003305.2) | Silent (SNP) | VAF 242/499 reads (48%) | catalogued as rs201241970; called by muse, mutect2, varscan2
- VDAC1 | c.99A>G p.T33= | Silent (SNP) | VAF 355/489 reads (73%) | called by muse, mutect2, varscan2
- WWOX | c.525C>T p.A175= | Silent (SNP) | VAF 157/316 reads (50%) | called by muse, mutect2, varscan2
- CCNYL2 | chr10:42475680 A>G | 5'Flank (SNP) | VAF 57/279 reads (20%) | called by muse, mutect2, varscan2
- Unknown | chrX:63561017 G>C | IGR (SNP) | VAF 147/285 reads (52%) | called by muse, mutect2, varscan2
